Surgical pathology report (de-identified scan), TCGA case TCGA-55-A492, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-A492-01A (Primary Tumor).

[page 1 of 5]
ring Physician:

DOB:

Age:

Gender

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. - J.) LUNG, RIGHT, UPPER LOBE, HILAR (N10R X 4), PERIBRONCHIAL (N11R), LOWER PARATRACHEAL (N4R), PULMONARY LIGAMENT (N9R), AND SUBCARINAL (N7) LYMPH NODES, WEDGE EXCISION WITH SUBSEQUENT LOBECTOMY, AND LYMPH NODE EXCISIONS:
- INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
- 1.2 cm in greatest dimension.
- Visceral pleural invasion: NOT IDENTIFIED.
- MARGIN STATUS: NEGATIVE.
- NINETEEN LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/19).
- Hyalinized nodules involving peribronchial and hilar lymph nodes, consistent with old granulomas.
- SEE TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Invasive adenocarcinoma, moderately differentiated.
Primary tumor: pT1a (1.2 cm in greatest dimension).
Regional lymph nodes: pN0 (0/19 lymph nodes).
Distant metastasis: N/A.
Pathologic stage: IA.
Lymphovascular invasion: Not identified.
Margin status: R0.

ICD-O-3

adenocarcinoma, NOS
8140/3

Site: lung, upper lobe c34.1

Lung Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol,

9-11-12
RD

[page 2 of 5]
Procedure:

Wedge excision with subsequent lobectomy and lymph node excisions.

Specimen type:**Lung, upper lobe.****Specimen laterality:****Right.****Specimen integrity:****Intact.****Tumor Features:****Tumor site:****Lung, right upper lobe.****Tumor size:****1.2 cm in greatest dimension.****Tumor focality:****Unifocal.****Histologic type:****Adenocarcinoma.****Histologic grade:****Moderately differentiated****Lymphovascular invasion:****Not identified.****Perineural invasion:****Not identified.****Visceral pleural invasion:****Not identified.****Tumor extension into extra-pulmonary structures:****Confined to the lung.****Treatment effect:****N/A.****Lymph Nodes:****Nineteen lymph nodes, negative for metastasis.****Margin Evaluation:****Negative, R0.****Distance to closest margin:****Bronchial margin:****Uninvolved by carcinoma.****Vascular margin:****Not involved by carcinoma.****Parenchymal margin:****Not involved by carcinoma.****Parietal pleural margin:****N/A.****Chest wall margin:****N/A.****Other margins:****Not applicable.****Pathologic tumor staging descriptors:****Primary tumor (pT):****pT1a (1.2 cm in greatest dimension).****Regional lymph nodes (pN):****pN0 (nineteen lymph nodes, negative for metastasis).****Distant metastasis (pM):****N/A.****Margin status (R):****R0.****Pathologic stage:****IA.****Additional pathologic findings:****Emphysematous changes. Hyalinized nodules within peribronchial and hilar lymph nodes consistent with old granulomas.**

[page 3 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Lung;Wedge resection right upper lobe
- B. Lymph node
- C. Lymph node
- D. Lymph node
- E. Lymph node;
- F. Lymph node;
- G. Lung;Right upper lobe
- H. Lymph node;
- I. Lymph node;
- J. Lymph node;

Clinical History/Operative Dx:

Right pulmonary nodule

Intraoperative Diagnosis:

- A. Wedge resection right upper lobe: Adenocarcinoma, margins negative.
- G. Right upper lobe: Bronchial margin negative for tumor The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. The specimen is labeled wedge resection right upper lobe and is received without fixative. It consists of a 12 x 4 x 2.5 cm wedge resection of lung tissue which has a partially fixed weight of 26 grams. The pleural surface is pink-tan and is inked purple. On serial sectioning, within the pulmonary parenchyma, there is a 1.2 cm pale tan demarcated nodule which is 0.3 cm from the staple line and 0.5 cm from the pleural surface. A representative section of this nodule is submitted for frozen section as FSA. The remaining pulmonary parenchyma is pale red and appears well-aerated. Representative sections are submitted. Section summary: A1) tissue remaining from frozen section, A2) remainder of pulmonary nodule, A3) lung tissue immediately adjacent to nodule, A4) uninvolved pulmonary parenchyma, A5) representative sections along central staple line closest to nodule.

B. The specimen is labeled and is received in formalin. It consists of a 0.5 x 0.2 x 0.2 cm fragment of anthracotic appearing tissue and a 0.1 cm fragment of pale tan tissue. The specimen is submitted in cassette B1.

Page 3
tinues... (FINAL)

[page 4 of 5]
FINAL SURGICAL PATHOLOGY REPORT

C. The specimen is labeled _____ and is received in formalin. It consists of a 0.4 cm fragment of dark red to anthracotic tissue and a 0.1 cm fragment of tan tissue. The specimen is submitted in cassette C1.

D. The specimen is labeled _____ and is received in formalin. It consists of two fragments of tan to anthracotic tissue which vary from 0.5 cm in maximum dimension to 0.7 x 0.5 x 0.5 cm. The larger fragment is inked. Both fragments are sectioned and the tissue is entirely submitted in cassette D1.

E. The specimen is labeled _____ and is received in formalin. It consists of a 0.4 cm fragment of tan to anthracotic tissue which is submitted intact in cassette E1.

F. The specimen is labeled _____ 1 and is received in formalin. It consists of a 0.9 x 0.5 x 0.4 cm fragment of slightly disrupted, red-brown tissue and a 0.1 cm fragment of anthracotic material. The largest specimen is serially sectioned and combined with the anthracotic material in cassette F1.

G. The specimen is labeled right upper lobe and is received in formalin. It consists of a lobe of lung which measures 16 x 5 x 4 cm and has a partially fixed weight of 112 grams. The pleural surfaces vary from pink to pale red-violet and are smooth. A metallic staple line is present along the medial edge of the hilum of the lung and a second staple line is present along the medial-anterior surface extending from the apical portion inferiorly and is 11.5 cm in length. The entire pleural surface is inked blue. At the hilum, the bronchial margin is identified and removed as a thin shave for frozen section as BFS. There are approximately six dark brown anthracotic peribronchial nodes. Dissection of the bronchi reveal no intrabronchial tumor. The pulmonary parenchyma is dark red and appears well-aerated and there are no other palpable masses. The presumed staple line from specimen A above is 2 cm from the closest bronchial margin. Representative sections are submitted. Section summary: G1) bronchial and partial vascular margins from frozen section, G2) additional vascular margin, G3) peribronchial nodes, G4) additional sections along anterior medial staple line, G5) additional apical lung tissue, G6) central lung parenchyma, G7) representative basilar lung parenchyma.

H. The specimen is labeled _____ and is received in formalin. It consists of a slightly disrupted fragment of lobulated fatty tissue measuring 4.2 x 2 x 1.3 cm. On gentle dissection, there is a single tan and partially anthracotic possible node which measures 2.4 x 0.8 x 0.7 cm. In the associated fatty tissue, there are four possible pale red additional nodes varying from 0.3-0.6 cm. The largest possible is serially sectioned and submitted in cassette H1. The smaller possible nodes are submitted intact in cassette H2.

I. The specimen is labeled _____ and is received in formalin. It consists of a 0.5 x 0.3 x 0.2 cm fragment of tan to anthracotic tissue which is submitted intact in cassette I1.

J. The specimen is labeled _____ and is received in formalin. It consists of two fragments of gray-tan and anthracotic tissue varying from 0.8-1 cm in maximum dimension. The tissue fragments are inked with contrasting colors. They are sectioned and submitted in cassette J1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

[page 5 of 5]
FINAL SURGICAL PATHOLOGY REPORT

- B. Sections demonstrate one lymph node, negative for metastasis.
- C. Sections demonstrate one lymph node, negative for metastasis.
- D. Sections demonstrate one lymph node, negative for metastasis. In addition, within the node are multiple round hyalinized nodules, consistent with old granulomata.
- E. Sections demonstrate one lymph node, negative for metastasis.
- F. Sections demonstrate one lymph node, negative for metastasis.
- G. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Six peribronchial lymph nodes are identified, and are negative for metastasis. In addition, two lymph nodes demonstrate round hyalinized nodules, consistent with old granulomata.
- H. Sections demonstrate five lymph nodes, negative for metastasis.
- I. Sections demonstrate one lymph node, negative for metastasis.
- J. Sections demonstrate 2 lymph nodes, negative for metastasis.

lw
8/30/12

Source: NCI Genomic Data Commons file bcdbdc8e-f39e-4604-9a15-e680c48c6100 (TCGA-55-A492.41F07E95-2D84-47CB-B78D-8F03D9C3D80E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).